Somatic mutation profile of tumor specimen MP2PRT-PARULL-TMP1-A (aliquot MP2PRT-PARULL-TMP1-A-1-0-D-A82A-36) from MP2PRT case MP2PRT-PARULL, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.0 years (1,101 days).
Specimen MP2PRT-PARULL-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 815a0341-3b2f-4b2a-af71-864e48a2be14.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARULL-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARULL-NB1-A-1-0-D-A82A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4d9ff71a-a123-4494-ac5b-c4c6009fba23

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 6, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SLC24A2 | c.747G>C p.L249F | Missense Mutation (SNP) | VAF 24/389 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53856378; called by muse, mutect2
- TECTA | c.487G>A p.V163M | Missense Mutation (SNP) | VAF 60/228 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs760441668; called by muse, mutect2, varscan2
- U2AF2 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 99/468 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV58272683; called by muse, mutect2, varscan2
- ZFHX4 | c.7184C>G p.P2395R | Missense Mutation (SNP) | VAF 49/598 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50534879; called by muse, mutect2
- IFNGR1 | c.1172G>T p.S391I | Missense Mutation (SNP) | VAF 74/309 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- OR1Q1 | c.689C>G p.S230* | Nonsense Mutation (SNP) | VAF 33/531 reads (6%) | called by muse, mutect2
- PRDM9 | c.776G>A p.G259E | Missense Mutation (SNP) | VAF 27/840 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CCDC88B | c.2265G>A p.L755= | Silent (SNP) | VAF 33/607 reads (5%) | called by muse, mutect2
- CELF4 | c.258G>T p.L86= | Silent (SNP) | VAF 37/449 reads (8%) | called by muse, mutect2
